Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5010, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5010-01A (Primary Tumor).

[page 1 of 4]
Ref. Source:

TCGA-BP-5010

Clinical Diagnosis & History:

Right renal mass and IVC thrombus.

Specimens Submitted:

- 1: Kidney, right, radical nephrectomy
- 2: SP: Segment vena caval thrombus and vena cava wall
- 3: SP: Proximal vena caval wall
- 4: Lymph nodes, paracaval and precaval, resection
- 5: Lymph nodes, hilar, resection
- 6: Lymph nodes, supra hilar, resection
- 7: Lymph nodes, interaortocaval, resection

DIAGNOSIS:

1. Kidney, right, radical nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
with spindle cell/sarcomatoid features

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 12.2 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia
Extends into renal pelvis
Involves renal sinus fat
Involves renal hilar fat

Renal Vein Invasion:

Vena cava invasion is identified
(see part 2) - Tumor also involves multiple medium- to large-caliber vessels in the region of the renal sinus/hilum

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Peritumoral reaction and two renal calculi

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

[page 2 of 4]
pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

2. Vena caval thrombus and segment of vena cava, resection:

Segment of venous wall and attached renal cell carcinoma (tumor thrombus).

3. Vena cava, proximal, resection:

Segment of venous wall negative for tumor.

4. Lymph nodes, paracaval and precaval, resection:

Lymph Nodes:

Not involved

Number of nodes examined:3

5. Lymph nodes, hilar, resection:

Lymph Nodes:

Not involved

Number of nodes examined:5

6. Lymph nodes, supra hilar, resection:

Lymph Nodes:

Not involved

Number of nodes examined:1

7. Lymph nodes, interaortocaval, resection:

Lymph Nodes:

Not involved

Number of nodes examined:6

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh labeled "right kidney, adrenal gland and vena caval thrombus" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 1205 g in total. The kidney measures 18.5 x 10.6 x 8.8 cm. The attached ureter measures 8.1 cm in length and 0.5 cm in diameter. The attached portion of inferior vena cava measures 0.6 cm in length and 3.9 cm in diameter with a protruding mass measuring 6.3 x 5.1 x 3.1 cm attached to the wall of inferior vena cava and completely obliterative the renal vein. The portion of renal artery measures 2.7 cm long and 0.4 cm in diameter. The renal artery and ureter margins are grossly unremarkable. An adrenal gland is identified, measures 5.5 x 3.5 x 1.3 cm and grossly appears unremarkable. The perinephric fat is of thickness ranging from 0.4 to 1.7 cm. The kidney is inked black and bivalved to reveal an irregular soft mass with variegated appearance, measures 12.2 x 9.8 x 8.9 cm, involving the entire upper pole and portion of the middle pole of the kidney. The mass appears to involve the perinephric fat, renal sinus and perihilar fat and grossly extends into the renal vessels. The pelvicaliceal system at the upper pole is completely compressed, while at the middle and lower poles, does not appear to be involved by the mass. Two 0.5 cm in diameter renal calculi are noted present in the middle pole. The remainder of the middle and lower pole shows a multiloculated cyst 2.4 cm in greatest dimension, which cannot be separated from the upper pole mass as no uninvolved renal parenchyma is grossly identified. Sections through the remainder of the kidney reveal a pink

[page 3 of 4]
brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.6 cm. No lymph nodes are grossly identified in the perinephric fat. Representative sections are submitted for [REDACTED] and for permanent sections. Specimen photographs taken.

Summary of sections:

UM -- ureteral margins

IVCM -- inferior vena cava margin

RAM -- renal artery margin

T-- tumor

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

RP -- renal pelvis representative sections

K -- representative sections kidney

MPK -- middle pole kidney

LPK -- lower pole kidney

A -- adrenal

2). The specimen is received fresh labeled "Segment vena caval thrombus and vena cava wall". It consists of multiple pieces of yellow-tan soft tissue measuring 3.5 x 3.5 x 0.4 cm in aggregate. The specimen is entirely submitted.

Summary of sections:

U-undesigned

3). The specimen is received in formalin, labeled "Proximal vena caval wall" and consists of a flattened piece of grossly unremarkable smooth pink-tan soft to rubbery tissue measuring 2.5 x 2 x 0.1 cm. A suture is identified at one end, and a staple line is identified at the other end. The specimen is serially sectioned from the sutured to the stapled end, with a suture and staples removed, and is entirely submitted.

Summary of sections:

SS-serial sections

4). The specimen is received in formalin, labeled "Paracaval and precaval nodes" and consists of three pink-tan lymph nodes ranging from 0.1 to 1.5 cm in greatest dimension, which are entirely submitted.

Summary of sections:

LN -- lymph nodes

BLN-- bisected lymph nodes

5). The specimen is received in formalin, labeled "Hilar lymph nodes" and consists of five pink-tan lymph nodes ranging from 0.3 to 1.4 cm in greatest dimension, which are entirely submitted.

Summary of sections:

LN -- lymph nodes

BLN-- bisected lymph nodes

6). The specimen is received in formalin, labeled "Suprahilar lymph node" and consists of a tan lymph node measuring 0.8 cm pouch is bisected and submitted entirely.

Summary of sections:

BLN - bisected lymph node

[page 4 of 4]
7). The specimen is received in formalin, labeled "Interaortacaval lymph nodes" and consists of six tan focally hemorrhagic lymph nodes ranging from 0.3 to 1.8 cm in greatest dimension, which are entirely submitted.

Summary of sections:

LN-lymph nodes submitted whole

BLN3 -- bisected lymph node number three

BLN - bisected lymph nodes (two nodes)

Summary of Sections:

Part 1: Kidney, right, radical nephrectomy

Block	Sect. Site	PCs
1	A	1
1	IVCM	1
1	K	1
1	LPK	1
1	MPK	1
1	RAM	1
4	RP	4
8	T	8
4	THF	4
5	TSF	5
1	UM	1

Part 2: SP: Segment vena caval thrombus and vena cava wall

Block	Sect. Site	PCs
2	u	2

Part 3: SP: Proximal vena caval wall

Block	Sect. Site	PCs
3	ss	3

Part 4: Lymph nodes, paracaval and precaval, resection

Block	Sect. Site	PCs
1	bln	1
1	ln	1

Part 5: Lymph nodes, hilar, resection

Block	Sect. Site	PCs
1	bln	1
1	ln	1

Part 6: Lymph nodes, suprahilar, resection

Block	Sect. Site	PCs
1	bln	1

Part 7: Lymph nodes, interaortocaval, resection

Block	Sect. Site	PCs
3	bln	3
2	bln3	3
1	ln	1

Source: NCI Genomic Data Commons file ef5231a2-e292-47ea-944b-40923f011fde (TCGA-BP-5010.77DF5C2F-D56A-4099-B066-A28EF25AAAAD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).